Somatic mutation profile of tumor specimen TCGA-CJ-4905-01A (aliquot TCGA-CJ-4905-01A-02D-1429-08) from TCGA case TCGA-CJ-4905, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 62.6 years (22,864 days).
Specimen TCGA-CJ-4905-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eaf11570-dc98-4b37-9ef4-9af4525be746.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CJ-4905-11A (Solid Tissue Normal), aliquot TCGA-CJ-4905-11A-01D-1429-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/37e24160-d741-4239-b0b3-4c62bca3fa1a

The open-access MAF lists 61 somatic variants for this specimen: 42 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 18, Frame Shift Del 6, Nonsense Mutation 3, Splice Region 1, Splice Site 1, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCE1 | c.1051C>A p.P351T | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV56847392; called by muse, mutect2, varscan2
- APOA5 | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs546060544, COSV57063471; called by muse, mutect2, varscan2
- AREL1 | c.1855A>C p.S619R | Missense Mutation (SNP) | VAF 63/226 reads (28%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.449); catalogued as COSV62666612; called by muse, mutect2, varscan2
- BOC | c.99C>T p.N33= | Splice Region (SNP) | VAF 29/129 reads (22%) | catalogued as rs762401448, COSV56352124; called by muse, mutect2, varscan2
- BPIFC | c.53T>A p.L18H | Missense Mutation (SNP) | VAF 46/160 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.707); catalogued as COSV55912794; called by muse, mutect2, varscan2
- CDCP1 | c.1486G>C p.G496R | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56105946; called by muse, mutect2, varscan2
- CFH | c.193G>A p.V65I | Missense Mutation (SNP) | VAF 57/187 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.017); catalogued as rs747978546, COSV62777683; called by muse, mutect2, varscan2
- CNP | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs782684248, COSV66368296; called by muse, mutect2
- DTNBP1 | c.401A>C p.H134P | Missense Mutation (SNP) | VAF 57/212 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.086); catalogued as COSV59040656; called by muse, mutect2, varscan2
- FAM162A | c.172G>A p.V58M | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV51658403; called by muse, mutect2, varscan2
- FLT3 | c.2306A>G p.E769G | Missense Mutation (SNP) | VAF 16/203 reads (8%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.831); catalogued as COSV54056256; called by muse, mutect2
- GPR84 | c.61T>C p.Y21H | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs774179979, COSV57209780; called by muse, mutect2, varscan2
- HSD17B1 | c.695A>G p.Q232R | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.314); catalogued as rs767357725, COSV56797848; called by muse, mutect2, varscan2
- INTS11 | c.898T>G p.F300V | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60088649; called by muse, mutect2, varscan2
- ITPRID2 | c.242G>A p.W81* | Nonsense Mutation (SNP) | VAF 19/82 reads (23%) | catalogued as COSV57472544; called by muse, mutect2, varscan2
- LRP2 | c.12227A>C p.E4076A | Missense Mutation (SNP) | VAF 59/180 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.081); catalogued as COSV55556601; called by muse, mutect2, varscan2
- MTMR8 | c.640A>T p.T214S | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.03); catalogued as COSV100878497, COSV66394223; called by muse, mutect2, varscan2
- NARS2 | c.1232G>T p.R411L | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55252272; called by muse, mutect2, varscan2
- OR4C15 | c.38C>A p.A13E | Missense Mutation (SNP) | VAF 70/260 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.06); catalogued as rs1565045282, COSV58953206; called by muse, mutect2, varscan2
- PHIP | c.5183A>C p.D1728A | Missense Mutation (SNP) | VAF 151/555 reads (27%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.058); catalogued as COSV51505320; called by muse, mutect2, varscan2
- PITPNM1 | c.1372T>C p.S458P | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.058); catalogued as COSV62708425; called by muse, mutect2, varscan2
- POLR3G | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 57/227 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.125); catalogued as rs866728572, COSV67625480; called by muse, mutect2, varscan2
- RBPJL | c.193T>C p.C65R | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV59213911; called by muse, mutect2, varscan2
- SDCCAG8 | c.1749T>A p.N583K | Missense Mutation (SNP) | VAF 47/184 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as COSV59410010; called by muse, mutect2, varscan2
- SIRT6 | c.107A>T p.E36V | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV59447412; called by muse, mutect2, varscan2
- SLC36A1 | c.725G>C p.R242T | Missense Mutation (SNP) | VAF 137/473 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV54654307; called by muse, mutect2, varscan2
- SLC7A13 | c.1115T>C p.I372T | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV52534886; called by muse, mutect2, varscan2
- TAFA2 | c.260-2A>T p.X87_splice | Splice Site (SNP) | VAF 49/221 reads (22%) | catalogued as COSV69180119; called by muse, mutect2, varscan2
- TASOR2 | c.5068A>C p.M1690L | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.225); catalogued as COSV60167800; called by muse, mutect2, varscan2
- TULP1 | c.298C>A p.R100S | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.14); catalogued as COSV57692788; called by muse, mutect2, varscan2
- UBXN10 | c.133C>T p.R45W | Missense Mutation (SNP) | VAF 48/159 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758101357, COSV66772264; called by muse, mutect2, varscan2
- YTHDC1 | c.1447G>T p.E483* (on ENST00000344157 / NM_001031732.4; = p.E465* on NM_133370.4) | Nonsense Mutation (SNP) | VAF 48/175 reads (27%) | catalogued as COSV60009446, COSV60010705; called by muse, mutect2, varscan2
- ZCCHC14 | c.1662del p.F555Lfs*5 (on ENST00000268616; = p.F692Lfs*5 on NM_015144.3) | Frame Shift Del (DEL) | VAF 49/207 reads (24%) | catalogued as COSV51889044; called by pindel, varscan2
- ZNF358 | c.383C>T p.T128I | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.047); catalogued as COSV51176378; called by muse, mutect2, varscan2
- ZNF627 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 54/178 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.095); catalogued as COSV63142308; called by muse, mutect2, varscan2
- ANK3 | c.3227_3228del p.E1076Afs*7 (on ENST00000280772 / NM_001320874.2; = p.E210Afs*7 on NM_001149.3) | Frame Shift Del (DEL) | VAF 26/101 reads (26%) | called by mutect2, pindel, varscan2
- ANKHD1-EIF4EBP3 | c.1908_1909del p.T637Sfs*15 | Frame Shift Del (DEL) | VAF 28/115 reads (24%) | called by mutect2, pindel, varscan2
- ANKRD29 | c.96_97insT p.N33* | Frame Shift Ins (INS) | VAF 23/127 reads (18%) | called by mutect2, pindel, varscan2
- ARMCX3 | c.752del p.L251Yfs*14 | Frame Shift Del (DEL) | VAF 41/183 reads (22%) | called by mutect2, pindel, varscan2
- COL6A6 | c.3727del p.V1243* | Frame Shift Del (DEL) | VAF 45/190 reads (24%) | called by mutect2, pindel, varscan2
- DNM1L | c.1346dup p.Y449* | Nonsense Mutation (INS) | VAF 24/120 reads (20%) | called by mutect2, pindel, varscan2
- PBRM1 | c.114_120del p.S39Ffs*4 | Frame Shift Del (DEL) | VAF 31/98 reads (32%) | called by mutect2, pindel, varscan2
- ABLIM1 | c.735G>A p.Q245= | Silent (SNP) | VAF 10/83 reads (12%) | catalogued as COSV53307572; called by muse, mutect2, varscan2
- AL592490.1 | c.1119G>T p.L373= | Silent (SNP) | VAF 56/318 reads (18%) | catalogued as COSV69426576; called by muse, mutect2, varscan2
- C21orf58 | c.807C>T p.A269= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as COSV52450027, COSV52450410; called by muse, mutect2, varscan2
- COL1A1 | c.2631T>A p.P877= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as COSV56805903; called by muse, mutect2, varscan2
- EPB41L1 | c.1098C>T p.V366= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV52437053, COSV52438731; called by muse, mutect2, varscan2
- EXPH5 | c.549C>A p.V183= | Silent (SNP) | VAF 36/134 reads (27%) | catalogued as COSV56203181; called by muse, mutect2, varscan2
- GUCY2F | c.1542G>A p.T514= | Silent (SNP) | VAF 63/192 reads (33%) | catalogued as rs367902822, COSV54303323; called by muse, mutect2, varscan2
- HECTD4 | c.3786C>G p.T1262= | Silent (SNP) | VAF 53/192 reads (28%) | catalogued as COSV61179639; called by muse, mutect2, varscan2
- MIIP | c.33G>T p.R11= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as COSV52427821; called by muse, mutect2, varscan2
- NEB | c.15594A>G p.E5198= | Silent (SNP) | VAF 25/101 reads (25%) | catalogued as COSV51422750; called by muse, mutect2, varscan2
- PIGT | c.822G>C p.L274= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV54126574; called by muse, mutect2, varscan2
- POLD1 | c.414C>T p.C138= | Silent (SNP) | VAF 35/110 reads (32%) | catalogued as COSV70955432; called by muse, mutect2, varscan2
- PXDN | c.2415G>A p.T805= | Silent (SNP) | VAF 28/69 reads (41%) | catalogued as rs754570178, COSV53234354; called by muse, mutect2, varscan2
- RAB33A | c.234G>T p.V78= | Silent (SNP) | VAF 31/145 reads (21%) | catalogued as COSV57061968, COSV57062948; called by muse, mutect2, varscan2
- RTL5 | c.243G>T p.G81= | Silent (SNP) | VAF 31/95 reads (33%) | catalogued as COSV65453728; called by muse, mutect2, varscan2
- SRCAP | c.5817T>C p.R1939= | Silent (SNP) | VAF 35/126 reads (28%) | catalogued as COSV52673748; called by muse, mutect2, varscan2
- TTN | c.43737G>A p.E14579= (on ENST00000591111; = p.E7155= on NM_003319.4) | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as COSV60107056; called by muse, mutect2
- ZNF527 | c.693G>A p.T231= | Silent (SNP) | VAF 55/230 reads (24%) | catalogued as rs73930983; called by muse, mutect2, varscan2
- ZNF396 | c.*844T>G | 3'UTR (SNP) | VAF 40/247 reads (16%) | catalogued as COSV60474364, COSV60474373; called by muse, mutect2, varscan2
